Gene-level copy-number profile of tumor specimen TCGA-MT-A67A-01A from TCGA case TCGA-MT-A67A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 85.3 years (31,161 days).
Specimen TCGA-MT-A67A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.7a549014-2452-4ed2-88ad-3025a29adf1c.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,735 have no estimate.
https://portal.gdc.cancer.gov/files/963f849e-d722-4780-9f4f-5e3e4645fe53

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 109; copy number 2: 45,033; copy number 3: 11,702; copy number 4: 27; copy number 6: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MT-A67A-01A-11D-A30D-01): tumor purity 0.5, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:133,117,004–133,119,052, 1 gene: AC011755.1.
- chr2:186,486,253–186,509,361, 2 genes: ZC3H15, DPRXP1.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr3:151,797,047–151,828,488, 2 genes: AC068647.2, AADAC.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:31,111,652–31,252,597, 3 genes, copy number 6: AC024940.1, AC024940.4, AC024940.2.
- chr17:46,029,916–46,225,389, 1 gene, copy number 6 (within-gene range 2–6): KANSL1.
- chr17:46,193,576–46,361,797, 6 genes, copy number 6: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B.

Autosomal genes at a single copy (total copy number 1): 109. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
